Gene-level copy-number profile of tumor specimen HCM-BROD-0597-C64-01B from HCMI case HCM-BROD-0597-C64, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Nephroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 1.5 years (533 days).
Specimen HCM-BROD-0597-C64-01B: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c009947b-ab5d-4e59-b9b5-ef24922adf42.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0597-C64-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/6adb2754-0f47-4719-a8ca-42651a2e44e0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 33; copy number 1: 5,931; copy number 2: 52,768; copy number 3: 131; copy number 4: 32; copy number 5: 5; copy number 15: 3.

Homozygous deletions (total copy number 0; autosomes only): 33 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,548,564–49,589,529, 7 genes: AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr11:70,862,790–70,872,368, 2 genes (within-gene range 0–1): SHANK2-AS3, MIR3664.
- chr14:18,395,626–18,596,310, 6 genes (within-gene range 0–1): CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9.
- chr14:19,024,090–19,055,551, 2 genes: AL589182.1, GRAMD4P4.
- chr14:19,124,807–19,337,730, 13 genes (within-gene range 0–1): AL589743.3, NBEAP5, AL589182.2, OR11H13P, AL589743.2, AL589743.4, CDRT15P13, NBEAP6, AL589743.1, TOMM40P1, DUXAP10, BMS1P17, AL929602.1.
- chr17:22,519,617–22,520,709, 1 gene: MTCYBP13.
- chr17:63,432,304–63,446,354, 1 gene: CYB561.
- chr19:24,078,481–24,080,669, 1 gene (within-gene range 0–1): AC092279.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:13,172,455–13,179,464, 1 gene, copy number 5: PRAMEF9.
- chr11:48,907,103–48,908,946, 1 gene, copy number 5: AC027369.5.
- chr14:18,967,434–19,003,752, 3 genes, copy number 15: POTEM, AL929601.3, RNU6-1239P.
- chr16:32,809,556–32,824,645, 2 genes, copy number 5: AC137761.1, AC137761.2.
- chr19:1,103,926–1,106,791, 1 gene, copy number 5: GPX4.

Autosomal genes at a single copy (total copy number 1): 3,075. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
